Gene-level copy-number profile of tumor specimen TCGA-DX-A7ET-01A from TCGA case TCGA-DX-A7ET, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 71.7 years (26,193 days).
Specimen TCGA-DX-A7ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.8f9de030-7765-4971-a307-418e05d6e9c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A7ET-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5e8b3aa-c77b-426d-87f4-97e2635f4024

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 2: 5,207; copy number 3: 2,409; copy number 4: 25,283; copy number 5: 4,186; copy number 6: 13,144; copy number 7: 2,197; copy number 8: 5,426; copy number 9: 983; copy number 10: 152; copy number 11: 177; copy number 12: 22; copy number 13: 269; copy number 15: 2; copy number 16: 13; copy number 19: 150; copy number 21: 47; copy number 24: 3; copy number 30: 5; copy number 43: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A7ET-01A-11D-A36I-01): tumor purity 0.49, ploidy 2.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:69,667,046–73,048,123, 55 genes: SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3.
- chr13:48,232,612–50,906,856, 59 genes (within-gene range 0–4): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,843 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:20,967,211–21,589,372, 7 genes, copy number 11–24: AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2.
- chr5:37,811,589–42,802,439, 72 genes, copy number 10–21 (within-gene range 4–21) (broad region; genes not listed).
- chr5:85,663,232–86,087,847, 4 genes, copy number 12: AC010595.1, RPS2P25, AC026414.1, PTP4A1P4.
- chr6:19,143,695–24,002,433, 51 genes, copy number 9: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58.
- chr6:41,239,520–41,548,621, 13 genes, copy number 10: RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276.
- chr6:45,097,496–45,099,260, 2 genes, copy number 15: AL138880.2, RBM22P4.
- chr6:46,852,522–47,042,350, 3 genes, copy number 13 (within-gene range 7–13): ADGRF5, ADGRF5-AS1, ADGRF1.
- chr7:70,972–727,650, 21 genes, copy number 9 (within-gene range 8–9): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1.
- chr8:74,798,784–75,352,327, 8 genes, copy number 12 (within-gene range 2–12): AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886.
- chr9:14,475–24,088,051, 339 genes, copy number 9–13 (broad region; genes not listed).
- chr9:33,613,848–43,045,120, 332 genes, copy number 13–19 (broad region; genes not listed).
- chr14:18,333,726–32,882,830, 578 genes, copy number 9–11 (broad region; genes not listed).
- chr15:97,215,812–99,733,561, 54 genes, copy number 9 (within-gene range 3–9): LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4.
- chr19:29,606,283–31,147,981, 24 genes, copy number 30–43: POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1.
- chr19:31,167,457–31,225,143, 1 gene, copy number 30 (within-gene range 2–30): LINC01791.
- chr19:40,121,311–46,343,433, 334 genes, copy number 9–13 (within-gene range 3–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
